TCGA case TCGA-06-A7TK — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/41685c5a-a548-483a-8a20-305ad8d61771

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 444 days (1.2 years).

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.1; Tissue or organ of origin: Frontal lobe; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 64.8 years (23,674 days); Year of diagnosis: 2013; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment dose: 60 Gy; Treatment outcome: Stable Disease; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 34 days; Days to treatment end: 76 days; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 113 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Days to treatment start: 342 days; Days to treatment end: 419 days (1.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Procarbazine; Days to treatment start: 342 days; Days to treatment end: 420 days (1.1 years); Treatment outcome: Progressive Disease.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 65.8 years (24,016 days); Days to diagnosis: 342 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 65.8 years (24,016 days); Days to diagnosis: 342 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 164 days; Disease response: With Tumor.
- Day 342 (post initial treatment): Progression or recurrence: Yes; Days to progression: 342 days; Days to recurrence: 342 days.
- Days to follow up: 444 days (1.2 years); Disease response: With Tumor.
- Karnofsky performance status: 70; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-A7TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 440 mg.
  Slide TCGA-06-A7TK-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-06-A7TK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 3: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 444 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 444 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 342 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-A7TK-01A-21D-A390-01): tumor purity 0.69, ploidy 1.96, whole-genome doublings 0.
